Surgical pathology report (de-identified scan), TCGA case TCGA-D5-5539, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-5539-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

Material: Multiple organ resection – segment of the large intestine

TCGA – D5 – 5539

Material collected on: Material received on:

Clinical diagnosis: tumour of the ascending colon, right half of the large intestine with the distal segment of the ileum.

Examination performed on:

Macroscopic description:

20 cm length of the large intestine, with periintestinal tissue sized 23 x 11 x 3cm, 13.8 cm segment of the small intestine, and a 6 cm appendix. Ulcerous tumour found in the mucosa, sized 3.3 x 5.2 x 0.8 cm. The lesion surrounding 60% of the intestine circumference, placed 15.3 cm from the proximal cut end, 15.0 cm from the distal cut end, and 1.4 cm from the ileocecal valve. Tumour accompanied by polyps of up to 2.0 cm in diameter.

Microscopic description:

Adenocarcinoma tubulare et mucinosum (G3).

Infiltratio carcinomatosa telae adiposae pericolicae.

Intestine ends free of neoplastic lesions.

Apart from the tumour: Adenoma tubulopapillare cum dysplasia minoris.

metastases carcinomatosae in lymphonodo (No I / IV).

Histopathological diagnosis:

Adenocarcinoma tubulare et mucinosum coli.

Metastases carcinomatosae in lymphonodo (No I / IV).

(G3, Dukes C, Astler-Colier C2, pT3, pN1)

TUBULAR AND MUCINOUS ADENOCARCINOMA OF THE COLON
METASTATIC LYMPH NODE C1/IV

Compliance validated by

Source: NCI Genomic Data Commons file 6935f07f-b44a-48cc-a39a-efd4f5b33790 (TCGA-D5-5539.1CFCF7E7-0886-4A24-9AB4-FCC10E998779.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).